Somatic mutation profile of tumor specimen TCGA-EO-A22X-01A (aliquot TCGA-EO-A22X-01A-11D-A17W-09) from TCGA case TCGA-EO-A22X, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 36.3 years (13,245 days).
Specimen TCGA-EO-A22X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99082246-ee55-41c2-83f4-faae88fac197.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EO-A22X-10A (Blood Derived Normal), aliquot TCGA-EO-A22X-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd05be4b-7741-4f74-82b0-9958cd57114c

The open-access MAF lists 10,742 somatic variants for this specimen: 8,524 protein-altering or splice-affecting, 1,938 silent, 280 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7,241, Silent 1,938, Nonsense Mutation 1,065, Intron 124, Splice Site 117, RNA 67, Splice Region 59, 5'Flank 30, 3'UTR 29, Frame Shift Ins 24, 5'UTR 16, 3'Flank 14.

Variants (750 of 10,742; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC2 | c.2443C>T p.R815* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as rs773850184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACADVL | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs112406105, CM990094, COSV50035822, COSV50039474; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.11410C>T p.R3804* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as rs767570081, COSV67994591; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APOB | c.10724G>A p.G3575D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.059); catalogued as rs1418775778; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARG1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 11/53 reads (21%) | catalogued as rs104893940, CM920106; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.6232C>T p.R2078* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs199422168, CM095684, COSV54125033; ClinVar: pathogenic; called by mutect2, varscan2
- ATP6AP1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as rs878853277, CM166855, COSV63895463; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BBS2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs567573386, CM114528, COSV55325564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.6952C>T p.R2318* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as rs80358920, CM993643, COSV66459219; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs397508296, CM920165, COSV50040595, COSV99140566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTCF | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1131691283, COSV50461486; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CUL4B | c.923dup p.L308Ffs*5 | Frame Shift Ins (INS) | VAF 12/50 reads (24%) | catalogued as rs1556216330; ClinVar: pathogenic; called by mutect2, varscan2
- DIS3 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs139907646, COSV66705997; called by muse, mutect2, varscan2
- DYSF | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 40/77 reads (52%) | catalogued as rs373585652, CM052862; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ELP1 | c.1461-1G>T p.X487_splice | Splice Site (SNP) | VAF 12/34 reads (35%) | catalogued as rs539544212, COSV65898470; ClinVar: likely pathogenic; called by muse, varscan2
- F11 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs753909969, CM082622, CM097413; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 17/39 reads (44%) | catalogued as rs80356517, CM040999, COSV55897351; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GAA | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs201896815, CM020003; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- HMBS | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs34413634, CM950641, COSV53829232; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HPRT1 | c.222C>A p.F74L | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs137852481, CM890066, CM952438, COSV53777024; ClinVar: pathogenic / other; called by muse, mutect2, varscan2
- IRF6 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 18/43 reads (42%) | catalogued as rs121434224, CM022390, CM092335, COSV100884042, COSV65419096, COSV65419721; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KIAA0586 | c.2308C>T p.R770* (on ENST00000619416 / NM_001244190.2; = p.R709* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs1064793157, CM1510289, COSV99708287; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as rs1379605717, COSV54149476; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as rs992161646, COSV104383282; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 18/48 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PIK3CB | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs1451809865, COSV56683754; called by muse, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 10/27 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PRLR | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as rs376188691, COSV51492949; ClinVar: pathogenic; called by muse, varscan2
- PSMD12 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs895130488, COSV62066198; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 10/44 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs797044910, CM110138, CM141438, COSV64293188, COSV64296384, COSV64307484; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 28/63 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PYGM | c.1456G>A p.G486S | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs926661627, COSV51216502; ClinVar: likely pathogenic; called by muse, varscan2
- RNPC3 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as rs918108896, CM141154, COSV100796392; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 11/36 reads (31%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, mutect2, varscan2
- SAMD9 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs1554336981; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN11A | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230622899, CM166896, COSV56568810, COSV56574613; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLC26A4 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs370588279, CM030956, COSV55914262; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SMPX | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs387906707, CM112964; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs1060502040, COSV66624800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNI3K | c.2302G>A p.E768K | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as rs202238194, COSV53950380; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99255174; called by muse, mutect2, varscan2
- A1CF | c.237C>T p.I79= | Splice Region (SNP) | VAF 13/37 reads (35%) | catalogued as rs777129780; called by muse, mutect2, varscan2
- A4GALT | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as rs1279378344; called by muse, mutect2, varscan2
- AARS2 | c.2405C>T p.A802V | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs141973247; called by muse, mutect2, varscan2
- AARS2 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV55114785; called by muse, mutect2, varscan2
- ABAT | c.1306C>T p.R436* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as rs1389255922, COSV51620481; called by muse, mutect2, varscan2
- ABCA10 | c.1694G>A p.R565Q | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776965436; called by muse, mutect2, varscan2
- ABCA10 | c.547A>G p.T183A | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV52227579; called by muse, mutect2, varscan2
- ABCA12 | c.3674G>A p.R1225Q (on ENST00000272895 / NM_173076.3; = p.R907Q on NM_015657.3) | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs761166029, COSV55956266; called by muse, mutect2, varscan2
- ABCA12 | c.3556G>A p.A1186T (on ENST00000272895 / NM_173076.3; = p.A868T on NM_015657.3) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.114); catalogued as COSV99790994; called by muse, mutect2, varscan2
- ABCA13 | c.921G>T p.E307D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs989980736, COSV101330176; called by muse, mutect2, varscan2
- ABCA13 | c.8596G>T p.E2866* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as rs551407561, COSV101446931; called by muse, varscan2
- ABCA13 | c.8603G>T p.R2868I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.862); catalogued as rs1228404263; called by muse, varscan2
- ABCA6 | c.4180G>A p.A1394T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1173154389; called by muse, mutect2, varscan2
- ABCA7 | c.4966C>T p.L1656F | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1376058025; called by muse, mutect2, varscan2
- ABCA9 | c.2515G>A p.V839M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61740908, COSV60622144; called by muse, mutect2, varscan2
- ABCA9 | c.1964G>A p.R655Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1406315291, COSV60623082, COSV60629236; called by muse, mutect2, varscan2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 14/40 reads (35%) | catalogued as rs1222604496, COSV55945529; called by muse, varscan2
- ABCB4 | c.2914G>T p.D972Y | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (1); PolyPhen possibly damaging (0.853); catalogued as COSV55941015; called by muse, mutect2, varscan2
- ABCB5 | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs768578610, COSV51702735, COSV51707828; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCB5 | c.3559G>A p.D1187N (on ENST00000404938 / NM_001163941.2; = p.D742N on NM_178559.6) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs759087816, COSV51703971; called by muse, mutect2, varscan2
- ABCB8 | c.884C>T p.T295M (on ENST00000297504 / NM_001282291.2; = p.T278M on NM_007188.5) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766650530, COSV52506583; called by muse, mutect2, varscan2
- ABCC11 | c.1358A>T p.K453M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62325055; called by muse, mutect2, varscan2
- ABCC12 | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100253423; called by muse, mutect2, varscan2
- ABCC6 | c.2214C>A p.F738L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV52741883; called by muse, mutect2, varscan2
- ABCC9 | c.3634C>A p.L1212I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53969122; called by muse, mutect2, varscan2
- ABCF2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV55186166; called by muse, mutect2, varscan2
- ABCG8 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as COSV55396395; called by muse, mutect2, varscan2
- ABHD12B | c.694G>T p.E232* (on ENST00000337334 / NM_001206673.2; = p.E155* on NM_181533.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs761299453; called by muse, varscan2
- ABHD2 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.251); catalogued as rs758636497, COSV100756194; called by muse, varscan2
- ABI1 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61015312; called by muse, mutect2, varscan2
- ABL2 | c.2050G>A p.E684K (on ENST00000502732 / NM_007314.4; = p.E669K on NM_005158.5) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV61012829; called by muse, mutect2, varscan2
- ABLIM1 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99522898; called by muse, mutect2, varscan2
- ABRAXAS2 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs11245379; called by muse, mutect2, varscan2
- AC013489.1 | c.1585G>A p.A529T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51552426; called by muse, mutect2, varscan2
- AC127029.3 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100033172, COSV100033338; called by muse, mutect2, varscan2
- AC132217.2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.125); catalogued as COSV100323991; called by muse, mutect2, varscan2
- ACACA | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs758519292; called by muse, mutect2, varscan2
- ACADM | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.611); catalogued as COSV63720044, COSV63720242; called by muse, mutect2, varscan2
- ACADS | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as CD122641; called by muse, varscan2
- ACCSL | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs377118963, CM142263; called by muse, mutect2, varscan2
- ACE2 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as rs1352194082, COSV53024322; called by muse, mutect2, varscan2
- ACKR1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.63); catalogued as rs751191108, COSV63671800; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACOX1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs1008291754; called by muse, mutect2, varscan2
- ACOX1 | c.111G>T p.E37D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV53131966; called by muse, mutect2, varscan2
- ACRV1 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as COSV100223575; called by muse, mutect2, varscan2
- ACSM3 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.241); catalogued as rs370404111; called by muse, mutect2, varscan2
- ACSM3 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV55503111; called by muse, mutect2, varscan2
- ACSM4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs368493928; called by muse, mutect2, varscan2
- ACSM5 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs772542022, COSV59375219; called by muse, mutect2, varscan2
- ACSS1 | c.1419C>A p.F473L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV60219399; called by muse, mutect2, varscan2
- ACSS2 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs757812388, COSV53628675; called by muse, varscan2
- ACSS3 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs747840747, COSV54089221; called by muse, mutect2, varscan2
- ACTBL2 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.138); catalogued as rs562161532, COSV70660977; called by muse, mutect2, varscan2
- ACTN2 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs780923255; called by muse, mutect2, varscan2
- ACTN4 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as COSV53143984; called by muse, mutect2, varscan2
- ACTR10 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs554639681, COSV54298006; called by muse, mutect2, varscan2
- ACTR1B | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs755547378; called by muse, mutect2, varscan2
- ACTR2 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.804); catalogued as rs1440834418, COSV53200285; called by muse, varscan2
- ACTR5 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as rs767290783; called by muse, mutect2, varscan2
- ACTR6 | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV99498691; called by muse, mutect2, varscan2
- ACVR1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1034717563; called by muse, mutect2, varscan2
- ACVR2B | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs754436899, COSV61703111; called by muse, mutect2, varscan2
- ADAM12 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770769845, COSV64106410; called by muse, mutect2, varscan2
- ADAM21 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs149756061, COSV50792703; called by muse, mutect2, varscan2
- ADAM21 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.281); catalogued as COSV99960575; called by muse, mutect2, varscan2
- ADAM22 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99717796; called by muse, mutect2, varscan2
- ADAM32 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101165540; called by muse, mutect2, varscan2
- ADAM33 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.173); catalogued as COSV62936796; called by muse, mutect2, varscan2
- ADAMTS13 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs587701622, COSV63020852; called by muse, mutect2, varscan2
- ADAMTS13 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as rs374154360; called by muse, mutect2, varscan2
- ADAMTS14 | c.89A>C p.H30P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs745572890; called by muse, mutect2, varscan2
- ADAMTS15 | c.2746C>T p.R916C | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774784317; called by muse, mutect2, varscan2
- ADAMTS16 | c.2070C>A p.F690L | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57010551; called by muse, mutect2, varscan2
- ADAMTS2 | c.1265G>A p.G422D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776291468; called by muse, varscan2
- ADAMTS20 | c.5320A>C p.N1774H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771199005; called by muse, mutect2, varscan2
- ADAMTS20 | c.2875G>T p.E959* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV67130559; called by muse, mutect2, varscan2
- ADAMTS3 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770164063, COSV99711906; called by muse, mutect2, varscan2
- ADAMTS5 | c.2281C>T p.R761* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs777065435, COSV53177958; called by muse, mutect2, varscan2
- ADAMTS5 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755042708, COSV53177133; called by muse, mutect2, varscan2
- ADAMTS5 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757685984, COSV53175432; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs368497511; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4016C>A p.S1339Y | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV54472201; called by muse, varscan2
- ADARB1 | c.1540C>T p.R514C (on ENST00000360697 / NM_001346687.2; = p.R474C on NM_001112.4) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs918813031, COSV100654082; called by muse, mutect2, varscan2
- ADCK1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as rs1349175856, COSV53078771, COSV99451589; called by muse, mutect2, varscan2
- ADCK1 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.007); catalogued as rs778880011, COSV53087565; called by muse, mutect2, varscan2
- ADCK2 | c.1043A>C p.E348A | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV50781656; called by muse, mutect2, varscan2
- ADCY4 | c.2183G>A p.G728D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1183918179; called by muse, mutect2, varscan2
- ADCY6 | c.3374G>A p.R1125Q | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as rs148471651; called by muse, mutect2, varscan2
- ADCY6 | c.3095C>T p.T1032M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57167028; called by muse, mutect2
- ADCY9 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773073326, COSV53571316; called by muse, varscan2
- ADCY9 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.238); catalogued as rs531124205; called by muse, varscan2
- ADCY9 | c.3214G>A p.E1072K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1162803356; called by muse, varscan2
- ADD3 | c.1388G>A p.R463Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758788444, COSV53326002; called by muse, mutect2, varscan2
- ADGRA3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs145174089; called by muse, mutect2
- ADGRB1 | c.1659C>A p.F553L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.998); catalogued as COSV60100502; called by muse, mutect2, varscan2
- ADGRB3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs766735540, COSV65381042; called by muse, mutect2, varscan2
- ADGRB3 | c.3527C>A p.S1176* | Nonsense Mutation (SNP) | VAF 38/94 reads (40%) | catalogued as COSV53234039; called by muse, varscan2
- ADGRE1 | c.2117G>A p.R706H | Missense Mutation (SNP) | VAF 63/133 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.156); catalogued as rs375499219; called by muse, mutect2, varscan2
- ADGRG4 | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs751591476; called by muse, mutect2
- ADGRG4 | c.7835C>T p.S2612L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV54961470; called by muse, mutect2, varscan2
- ADGRG6 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488416802; called by muse, mutect2, varscan2
- ADGRG6 | c.461G>T p.R154M | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99747543; called by muse, mutect2, varscan2
- ADGRL1 | c.3764G>A p.R1255Q (on ENST00000340736 / NM_001008701.3; = p.R1250Q on NM_014921.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as rs775561998, COSV61566632; called by muse, mutect2, varscan2
- ADGRL2 | c.2539C>T p.L847F (on ENST00000370717 / NM_001366005.1; = p.L834F on NM_012302.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54690045; called by muse, mutect2, varscan2
- ADGRL3 | c.971G>A p.R324Q (on ENST00000506720 / NM_001322402.2; = p.R256Q on NM_015236.6) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1285211466; called by muse, mutect2, varscan2
- ADGRV1 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.395); catalogued as COSV101315424; called by muse, mutect2, varscan2
- ADGRV1 | c.14404C>T p.R4802* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as rs1236715896, CM0911268, COSV67978996; called by muse, mutect2, varscan2
- ADGRV1 | c.16225C>T p.R5409* | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as rs199806093; called by muse, mutect2, varscan2
- ADIPOR2 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777599853, COSV63947216; called by muse, mutect2, varscan2
- ADNP2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as rs778460457; called by muse, mutect2, varscan2
- ADPRH | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1412057111; called by muse, mutect2, varscan2
- ADRA2B | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 9/24 reads (38%) | catalogued as rs371716124; called by muse, mutect2, varscan2
- AEBP1 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs150909656; called by muse, mutect2, varscan2
- AFAP1L2 | c.1471G>A p.D491N | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.2); PolyPhen probably damaging (1); catalogued as rs1236780680, COSV58415803; called by muse, mutect2, varscan2
- AFAP1L2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748304962, COSV58412500; called by muse, mutect2, varscan2
- AFDN | c.4082G>A p.R1361Q | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs545826394, COSV60049712; called by muse, varscan2
- AFF2 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV53983823; called by muse, mutect2, varscan2
- AFF2 | c.1628C>A p.S543Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs782144498, COSV53988390; called by muse, mutect2, varscan2
- AFF2 | c.1719G>T p.K573N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV54004615; called by muse, mutect2, varscan2
- AFF2 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV54004489; called by muse, mutect2, varscan2
- AFTPH | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as rs1179899621, COSV53217911; called by muse, mutect2, varscan2
- AGAP1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs372718570, COSV100364772; called by muse, mutect2, varscan2
- AGAP3 | c.2302C>T p.L768F (on ENST00000622464; = p.L804F on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370213483; called by muse, mutect2, varscan2
- AGAP4 | c.1131G>T p.K377N | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99067966; called by muse, mutect2, varscan2
- AGBL2 | c.2414dup p.L805Ffs*6 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs748435789; called by pindel, varscan2
- AGL | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV54049072, COSV54059254, COSV99648854; called by muse, mutect2, varscan2
- AGL | c.1406G>A p.R469Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.801); catalogued as rs759535258, COSV54050692; called by muse, mutect2, varscan2
- AGT | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64183981, COSV64184605; called by muse, mutect2, varscan2
- AGTPBP1 | c.701-1G>T p.X234_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100430252; called by muse, mutect2, varscan2
- AGTPBP1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768166878; called by muse, mutect2, varscan2
- AGXT2 | c.1195A>G p.K399E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV99183796; called by muse, mutect2, varscan2
- AGXT2 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs754018269, COSV51486117; called by muse, mutect2, varscan2
- AHCTF1 | c.5897G>A p.R1966H (on ENST00000366508; = p.R1940H on NM_015446.5) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs376171651; called by muse, mutect2, varscan2
- AHCTF1 | c.363C>A p.F121L (on ENST00000366508; = p.F95L on NM_015446.5) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as COSV58246083; called by muse, mutect2, varscan2
- AHI1 | c.2755G>A p.D919N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773959302; called by muse, mutect2, varscan2
- AHNAK2 | c.17209C>T p.R5737* | Nonsense Mutation (SNP) | VAF 29/72 reads (40%) | catalogued as rs756633208; called by muse, varscan2
- AHNAK2 | c.16645G>A p.E5549K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.194); catalogued as COSV60920665; called by muse, mutect2, varscan2
- AHNAK2 | c.13612G>A p.E4538K | Missense Mutation (SNP) | VAF 65/166 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.858); catalogued as rs199737542; called by muse, mutect2, varscan2
- AHNAK2 | c.4846G>A p.D1616N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs773853819, COSV100315997; called by muse, mutect2, varscan2
- AIF1L | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1156713903; called by muse, mutect2, varscan2
- AIMP1 | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs747675209, COSV63639130; called by muse, mutect2, varscan2
- AIMP1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs777680841, COSV63639419; called by muse, mutect2, varscan2
- AIRE | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs766103427; called by muse, mutect2, varscan2
- AK9 | c.5432C>A p.S1811Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV101413984; called by muse, mutect2, varscan2
- AK9 | c.3522G>T p.K1174N | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs147042397; called by muse, varscan2
- AKAP10 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs920251209, COSV56733643; called by muse, varscan2
- AKAP14 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs978267657, COSV57629200; called by muse, varscan2
- AKAP3 | c.1782C>A p.F594L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.228); catalogued as rs1157246795; called by muse, mutect2, varscan2
- AKAP9 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0.029); catalogued as rs758729015, COSV62344777; called by muse, mutect2, varscan2
- AKAP9 | c.5893C>A p.L1965I (on ENST00000359028; = p.L1933I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.113); catalogued as COSV62342675; called by muse, mutect2, varscan2
- AKAP9 | c.6943G>T p.E2315* (on ENST00000359028; = p.E2291* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV62343078; called by muse, mutect2, varscan2
- AKAP9 | c.9208C>T p.R3070W (on ENST00000359028; = p.R3046W on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs780099038, COSV62340743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKAP9 | c.10516C>A p.L3506I (on ENST00000359028; = p.L3482I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV62350106; called by muse, mutect2, varscan2
- AKNAD1 | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV64172137; called by muse, mutect2, varscan2
- AKT2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776161532; called by muse, mutect2, varscan2
- AKTIP | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as rs141560947; called by muse, varscan2
- AL121899.2 | c.266C>T p.T89M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766435407, COSV101198725, COSV67349952; called by muse, mutect2, varscan2
- AL133500.1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious, low confidence (0); catalogued as rs776579011; called by muse, mutect2, varscan2
- AL592490.1 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69427711; called by muse, mutect2, varscan2
- AL645922.1 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV100191455; called by muse, mutect2, varscan2
- AL669918.1 | c.2346G>T p.R782S | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as COSV71270839; called by muse, mutect2, varscan2
- ALAS1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as rs1415507417, COSV59628875; called by muse, mutect2, varscan2
- ALB | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV55740248; called by muse, mutect2, varscan2
- ALDH3A1 | c.813C>A p.F271L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1273343585, COSV56736140; called by muse, mutect2, varscan2
- ALDOB | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767812270, COSV66398262; called by muse, mutect2, varscan2
- ALDOC | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs761240800, COSV52024699; called by muse, varscan2
- ALG11 | c.1146G>T p.K382N | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as rs754572359, COSV101584404; called by muse, mutect2, varscan2
- ALG11 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201526759, COSV73000831; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALG14 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as rs200774756; called by muse, mutect2, varscan2
- ALG2 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1350412580, COSV53059855; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALG9 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV101211859; called by muse, mutect2, varscan2
- ALOX15 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as rs767358542; called by muse, mutect2, varscan2
- ALOX15B | c.927C>A p.F309L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV66479031, COSV66479840; called by muse, mutect2, varscan2
- ALOXE3 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 29/68 reads (43%) | catalogued as COSV59075341; called by muse, mutect2, varscan2
- ALOXE3 | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV59075656; called by muse, mutect2, varscan2
- ALPI | c.888G>T p.E296D | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.059); catalogued as COSV55016136; called by muse, mutect2, varscan2
- ALPK2 | c.5704G>T p.E1902* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV64490749; called by muse, mutect2, varscan2
- AMACR | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.386); catalogued as rs975712828; called by muse, mutect2
- AMBRA1 | c.1331C>T p.S444L (on ENST00000458649 / NM_001367468.1; = p.S354L on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs139222125, COSV100095853; called by muse, mutect2, varscan2
- AMER1 | c.1524C>A p.F508L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as rs1288332581, COSV57659044, COSV57663326; called by muse, mutect2, varscan2
- AMER3 | c.1865C>T p.S622L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs541254437, COSV100365820; called by muse, mutect2, varscan2
- AMFR | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs746062824, COSV51923716; called by muse, mutect2, varscan2
- AMMECR1 | c.719G>T p.R240I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867942217; called by muse, mutect2, varscan2
- ANAPC15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.04); catalogued as rs982888986, COSV56191427; called by muse, mutect2, varscan2
- ANK2 | c.6820C>T p.R2274C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs140258681; called by muse, mutect2, varscan2
- ANK2 | c.8062C>T p.R2688* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as rs765199439, COSV52154516; called by muse, mutect2, varscan2
- ANK2 | c.10187C>A p.S3396Y | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV100002141, COSV52184715; called by muse, mutect2, varscan2
- ANKEF1 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as rs151126947; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2375G>T p.R792I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV51846427, COSV51853752; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4448C>T p.S1483L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs775180361, COSV51843131; called by muse, mutect2, varscan2
- ANKIB1 | c.2188C>T p.R730W | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1004797187; called by muse, mutect2, varscan2
- ANKK1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as rs375367141; called by muse, varscan2
- ANKRD10 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs755781873, COSV99941018; called by muse, mutect2, varscan2
- ANKRD11 | c.2094G>T p.E698D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV104396154; called by muse, mutect2, varscan2
- ANKRD22 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs758073859, COSV64236209; called by muse, mutect2, varscan2
- ANKRD26 | c.4288C>A p.L1430I | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV101063365, COSV65777269; called by muse, mutect2, varscan2
- ANKRD30A | c.1212G>T p.E404D (on ENST00000611781; = p.E348D on NM_052997.2) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.217); catalogued as COSV64605137; called by muse, mutect2, varscan2
- ANKRD30A | c.1479G>T p.K493N (on ENST00000611781; = p.K437N on NM_052997.2) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.341); catalogued as COSV64606200; called by muse, mutect2, varscan2
- ANKRD30A | c.1615G>T p.E539* (on ENST00000611781; = p.E483* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 30/88 reads (34%) | catalogued as COSV64608080; called by muse, mutect2, varscan2
- ANKRD30A | c.2125G>T p.E709* (on ENST00000611781; = p.E653* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as rs1180165839, COSV100654280; called by muse, mutect2, varscan2
- ANKRD30A | c.2982G>T p.K994N (on ENST00000611781; = p.K938N on NM_052997.2) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64606049, COSV64610801; called by muse, mutect2
- ANKRD44 | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.527); catalogued as rs1442756810; called by mutect2, varscan2
- ANKRD49 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57059788; called by muse, mutect2, varscan2
- ANKRD50 | c.3872C>A p.S1291Y | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV101539047, COSV72385340; called by muse, mutect2, varscan2
- ANKRD50 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs368187440; called by muse, mutect2, varscan2
- ANKRD6 | c.1089G>T p.K363N | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.165); catalogued as COSV60229459; called by muse, mutect2, varscan2
- ANKRD7 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs532626106, COSV54554860; called by muse, mutect2, varscan2
- ANKS1A | c.2170G>A p.D724N | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.993); catalogued as rs1257206556, COSV64462125; called by muse, mutect2, varscan2
- ANKS1B | c.1595T>G p.I532S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV61375509; called by muse, mutect2, varscan2
- ANKS4B | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs531162767, COSV61138806; called by muse, varscan2
- ANO2 | c.1476G>T p.E492D (on ENST00000356134 / NM_001278597.3; = p.E496D on NM_001278596.3) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs748400409, COSV100501171; called by muse, varscan2
- ANO2 | c.1022A>C p.K341T (on ENST00000356134 / NM_001278597.3; = p.K345T on NM_001278596.3) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59013061; called by muse, mutect2, varscan2
- ANO4 | c.2734G>T p.D912Y (on ENST00000392977 / NM_001286615.2; = p.D877Y on NM_178826.4) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV54604791; called by muse, mutect2, varscan2
- ANO6 | c.1904G>A p.R635Q | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs745565220; called by muse, mutect2, varscan2
- ANOS1 | c.1439G>A p.G480D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.086); catalogued as COSV52918689; called by muse, mutect2, varscan2
- ANXA8 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1428700586; called by muse, mutect2, varscan2
- AOC2 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs528413349; called by muse, mutect2, varscan2
- AP002512.3 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV54406614; called by muse, mutect2
- AP3B1 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.283); catalogued as rs193920974; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP3B2 | c.2564C>T p.S855L (on ENST00000261722; = p.S849L on NM_004644.5) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.286); catalogued as rs768482027, COSV55609940; called by muse, mutect2, varscan2
- AP3B2 | c.2102C>T p.S701L | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as rs777932732; called by muse, mutect2, varscan2
- AP4E1 | c.1234A>C p.K412Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99956678; called by muse, mutect2, varscan2
- APBB1IP | c.661C>A p.L221I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.74); catalogued as rs1263345764; called by muse, mutect2, varscan2
- APC | c.2945C>T p.S982L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs139773221, COSV57396050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APC | c.5582C>A p.S1861Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD961780, COSV104379185, COSV57328606; called by muse, mutect2, varscan2
- APC | c.6086C>A p.S2029Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99964923, COSV99964952; called by mutect2, varscan2
- APC | c.7720C>A p.L2574I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs876659753, COSV57384137; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APH1B | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV56013865; called by muse, mutect2, varscan2
- APOB | c.11230C>A p.L3744I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.67); PolyPhen benign (0.297); catalogued as COSV51928541; called by muse, mutect2, varscan2
- APOB | c.10922C>A p.S3641Y | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99265512, COSV99268083; called by muse, mutect2, varscan2
- APOB | c.10568C>T p.S3523F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.373); catalogued as rs1363799468; called by muse, mutect2, varscan2
- APOBR | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100112403, COSV60491876; called by muse, mutect2, varscan2
- APOBR | c.1838G>A p.G613E (on ENST00000431282; = p.G622E on NM_018690.4) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1450556918; called by muse, mutect2, varscan2
- APOOL | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64271606; called by muse, mutect2, varscan2
- APP | c.2292C>A p.F764L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382239795, COSV60994133; called by muse, mutect2, varscan2
- AQR | c.3053G>A p.R1018Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370660482, COSV50031222; called by muse, mutect2, varscan2
- AQR | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs747906891, COSV104381111; called by muse, varscan2
- AR | c.1886-1G>T p.X629_splice | Splice Site (SNP) | VAF 17/33 reads (52%) | catalogued as CS024559, COSV65954104, COSV65957130; called by muse, mutect2, varscan2
- ARAF | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.023); catalogued as COSV51691546, COSV51691983; called by muse, mutect2, varscan2
- ARAP1 | c.3901G>A p.D1301N (on ENST00000393609 / NM_001040118.2; = p.D1056N on NM_015242.4) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1214366352, COSV61992848; called by muse, mutect2, varscan2
- ARAP3 | c.1750G>T p.D584Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761540433; called by muse, mutect2, varscan2
- ARFGEF2 | c.1475C>A p.S492Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64211331, COSV64213467; called by muse, mutect2, varscan2
- ARFGEF2 | c.3376C>T p.R1126W | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64213593; called by muse, mutect2, varscan2
- ARHGAP11A | c.2128G>T p.D710Y | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55705886, COSV55706251; called by muse, mutect2, varscan2
- ARHGAP15 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV54480793, COSV54514102; called by muse, mutect2, varscan2
- ARHGAP20 | c.1133A>C p.K378T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs776674201; called by muse, mutect2, varscan2
- ARHGAP20 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.421); catalogued as rs746633900, COSV52811161; called by muse, mutect2, varscan2
- ARHGAP21 | c.4002C>T p.H1334= | Splice Region (SNP) | VAF 20/54 reads (37%) | catalogued as rs148522047; called by muse, varscan2
- ARHGAP21 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV57604563; called by muse, varscan2
- ARHGAP26 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50827340; called by muse, mutect2, varscan2
- ARHGAP28 | c.1632C>A p.F544L (on ENST00000383472 / NM_001366230.1; = p.F385L on NM_001010000.3) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51642619; called by muse, mutect2, varscan2
- ARHGAP29 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs757995655, COSV53109880; called by muse, mutect2, varscan2
- ARHGAP30 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV63516021; called by muse, mutect2, varscan2
- ARHGAP30 | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200609833, COSV63517565; called by muse, mutect2, varscan2
- ARHGAP35 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs1320111356; called by muse, mutect2, varscan2
- ARHGAP35 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs1322723304, COSV68330383, COSV68334239; called by muse, mutect2, varscan2
- ARHGAP44 | c.610T>G p.F204V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99310916; called by muse, mutect2, varscan2
- ARHGAP6 | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as rs748815220, COSV100273710; called by mutect2, varscan2
- ARHGEF10L | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as rs146853605; called by muse, mutect2, varscan2
- ARHGEF11 | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 33/74 reads (45%) | catalogued as COSV63811869; called by muse, mutect2, varscan2
- ARHGEF12 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs768635441; called by muse, mutect2, varscan2
- ARHGEF2 | c.286G>A p.A96T (on ENST00000361247 / NM_001162383.2; = p.A69T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as rs1306042222; called by muse, mutect2, varscan2
- ARHGEF28 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs753100535; called by muse, mutect2, varscan2
- ARHGEF28 | c.2156C>A p.S719Y | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV55259750; called by muse, mutect2, varscan2
- ARHGEF35 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs779913268; called by muse, mutect2, varscan2
- ARHGEF40 | c.1856T>G p.L619R | Missense Mutation (SNP) | VAF 56/169 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.332); catalogued as rs770213867; called by muse, mutect2, varscan2
- ARHGEF6 | c.1271G>T p.R424I | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs1064796226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF6 | c.923+1G>T p.X308_splice | Splice Site (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99166417; called by muse, mutect2, varscan2
- ARHGEF7 | c.348G>T p.Q116H (on ENST00000375741 / NM_001113511.2; = p.Q95H on NM_145735.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.02); catalogued as COSV54541840; called by muse, mutect2, varscan2
- ARHGEF9 | c.1311T>G p.I437M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV99492106; called by muse, mutect2, varscan2
- ARHGEF9 | c.407G>T p.R136I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53636625; called by muse, mutect2, varscan2
- ARMC4 | c.2381G>A p.R794Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs747260565, COSV100537052; called by muse, mutect2, varscan2
- ARMC4 | c.2241G>T p.E747D | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV59467132; called by muse, mutect2, varscan2
- ARMC4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as rs752348839, COSV100536620, COSV59458741; called by muse, mutect2, varscan2
- ARMC9 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1334293953, COSV63020478; called by muse, mutect2, varscan2
- ARMCX3 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.257); catalogued as rs1234962087, COSV100362336; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63439544; called by muse, mutect2, varscan2
- ARMH3 | c.2055C>A p.F685L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV53306271, COSV53307324, COSV53307859; called by muse, mutect2, varscan2
- ARMH4 | c.671A>C p.K224T | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV99957785; called by muse, mutect2, varscan2
- ARNTL | c.1490G>A p.R497Q (on ENST00000403290 / NM_001297719.2; = p.R496Q on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.17); catalogued as rs1343504455; called by muse, mutect2, varscan2
- ARPC3 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.381); catalogued as rs200224002; called by muse, mutect2, varscan2
- ARSG | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as rs769238862, COSV100048418; called by muse, mutect2, varscan2
- ARSI | c.1259G>A p.R420H | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147847092; called by muse, mutect2, varscan2
- ARSJ | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs1276080356, COSV59540085; called by muse, mutect2, varscan2
- ARSJ | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59539858; called by muse, mutect2, varscan2
- ART4 | c.68G>T p.R23I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV57451950, COSV57453642; called by muse, mutect2, varscan2
- ASAP2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748052568, COSV55633047; called by muse, varscan2
- ASAP3 | c.1759G>T p.E587* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100369256; called by muse, mutect2, varscan2
- ASB11 | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV60354282, COSV60356455; called by muse, mutect2, varscan2
- ASB5 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751252627, COSV56668485; called by muse, mutect2, varscan2
- ASB6 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs761792727, COSV52965513; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASCC3 | c.6084T>G p.N2028K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV100976854; called by muse, mutect2, varscan2
- ASH1L | c.8902C>T p.R2968* (on ENST00000368346 / NM_001366177.2; = p.R2963* on NM_018489.3) | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as rs143633976, COSV64206483; called by muse, mutect2, varscan2
- ASH1L | c.3645G>T p.E1215D | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs1332354740, COSV100853420, COSV64212648; called by muse, mutect2, varscan2
- ASH1L | c.1122G>T p.K374N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as rs754704335; called by muse, mutect2, varscan2
- ASPH | c.1792C>T p.R598* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as rs1306079293; called by muse, mutect2, varscan2
- ASPM | c.5186G>A p.R1729Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.227); catalogued as rs768999000, COSV54128816, COSV54128933; called by muse, mutect2, varscan2
- ASPN | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1564330399, COSV65016018; called by muse, mutect2, varscan2
- ASTN1 | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as rs1357604735, COSV62493153; called by muse, mutect2, varscan2
- ATE1 | c.1231C>A p.H411N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200140033; called by muse, varscan2
- ATF6 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as rs146640460, COSV63408740; called by muse, mutect2, varscan2
- ATF6 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as rs760001414, COSV63405877; called by muse, mutect2, varscan2
- ATF7IP | c.1195G>T p.E399* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV53765876; called by muse, mutect2, varscan2
- ATF7IP | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.56); catalogued as rs761585027; called by muse, mutect2, varscan2
- ATG2B | c.5428G>T p.E1810* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99952224; called by muse, mutect2, varscan2
- ATG2B | c.1127G>T p.R376I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV104417702; called by muse, varscan2
- ATG2B | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.357); catalogued as rs778368919, COSV100737778, COSV63421927; called by muse, varscan2
- ATG4C | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV58605034; called by muse, mutect2, varscan2
- ATM | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.049); catalogued as rs145355104; ClinVar: uncertain significance; called by muse, varscan2
- ATM | c.4363A>C p.S1455R | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV53736867; called by muse, mutect2, varscan2
- ATMIN | c.2437A>G p.T813A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs773806057; called by muse, mutect2, varscan2
- ATP10A | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1407076325, COSV100791327; called by muse, mutect2, varscan2
- ATP10A | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV63512994; called by muse, mutect2, varscan2
- ATP10B | c.3396C>A p.F1132L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV59153682; called by muse, mutect2
- ATP10D | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.103); catalogued as rs149671949; called by muse, mutect2
- ATP10D | c.1110T>G p.F370L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV99905077; called by muse, mutect2, varscan2
- ATP11A | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs777953338; called by muse, mutect2, varscan2
- ATP11A | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as rs768448846; called by muse, mutect2, varscan2
- ATP11B | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as rs1295948091, COSV60026923; called by muse, mutect2, varscan2
- ATP11C | c.1909G>A p.D637N | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1569452773, COSV59578020; called by muse, mutect2, varscan2
- ATP12A | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV54514387; called by muse, mutect2, varscan2
- ATP13A2 | c.2835C>A p.F945L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1227660193, COSV100454278; called by muse, mutect2, varscan2
- ATP13A3 | c.3662C>T p.A1221V (on ENST00000645319 / NM_001367549.1; = p.A1191V on NM_024524.3) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as rs773710020, COSV55465165; called by muse, mutect2, varscan2
- ATP13A5 | c.3077G>T p.R1026I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV60868956; called by muse, mutect2, varscan2
- ATP13A5 | c.1020G>T p.E340D | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.135); catalogued as COSV100665693; called by muse, mutect2, varscan2
- ATP1A1 | c.613A>C p.I205L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.024); catalogued as COSV55190406; called by muse, mutect2, varscan2
- ATP1A4 | c.305A>C p.K102T | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs771691718; called by muse, mutect2, varscan2
- ATP1A4 | c.2257G>A p.D753N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as rs750851195, COSV63625375; called by muse, mutect2, varscan2
- ATP1B4 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99486576; called by muse, mutect2, varscan2
- ATP2A1 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63920944, COSV63922283; called by muse, mutect2, varscan2
- ATP2B3 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs781787078, COSV54850391; called by muse, mutect2, varscan2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP6AP2 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101011432, COSV65797478; called by muse, varscan2
- ATP6V0A4 | c.2134G>T p.E712* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV59475302; called by muse, mutect2, varscan2
- ATP6V0A4 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374791119, COSV59474220; called by muse, mutect2, varscan2
- ATP6V1C2 | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55360736; called by muse, mutect2, varscan2
- ATP6V1C2 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV55358534; called by muse, mutect2, varscan2
- ATP7A | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV58444929; called by muse, mutect2, varscan2
- ATP7A | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.655); catalogued as rs782555092; called by muse, mutect2, varscan2
- ATP8A2 | c.595A>C p.M199L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.811); catalogued as COSV99681836; called by muse, varscan2
- ATP8A2 | c.1724G>T p.R575I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1382573117; called by muse, mutect2, varscan2
- ATP8A2 | c.2586G>T p.K862N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as rs772849148; called by muse, mutect2, varscan2
- ATP8B1 | c.716T>G p.F239C | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV52179796; called by muse, mutect2, varscan2
- ATP8B1 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1305626000, COSV52174166; called by muse, mutect2, varscan2
- ATPAF1 | c.478G>T p.E160* (on ENST00000574428; = p.E183* on NM_022745.4) | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV100236256; called by muse, mutect2, varscan2
- ATR | c.6938C>A p.S2313Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as rs1446847444, COSV63383908; called by muse, mutect2
- ATR | c.6719G>A p.S2240N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs765461897, COSV100638630; called by muse, mutect2, varscan2
- ATRNL1 | c.2840G>T p.R947I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100369542; called by muse, mutect2, varscan2
- ATRX | c.7327A>C p.N2443H | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV64873541; called by muse, mutect2, varscan2
- ATRX | c.2351C>A p.S784Y | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV64881851; called by muse, mutect2, varscan2
- ATXN2 | c.3838G>A p.A1280T (on ENST00000550104; = p.A1120T on NM_002973.4) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs749624885; called by muse, mutect2, varscan2
- ATXN2L | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100294330, COSV57376322; called by muse, mutect2, varscan2
- ATXN7L3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs1297279073, COSV66989658; called by muse, mutect2, varscan2
- AUNIP | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs765800562, COSV65353484; called by muse, mutect2, varscan2
- AVIL | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs549145073, COSV57680547; called by muse, mutect2, varscan2
- AVPR2 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as rs1557100765; called by muse, mutect2, varscan2
- AXDND1 | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 23/54 reads (43%) | catalogued as COSV62647920; called by muse, mutect2, varscan2
- AZGP1 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52797514, COSV52798449; called by muse, mutect2, varscan2
- B3GNT4 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs942692043, COSV57336917; called by muse, mutect2, varscan2
- B4GALNT2 | c.456T>G p.F152L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1342389128; called by muse, mutect2, varscan2
- B4GALT1 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778179705; called by muse, mutect2, varscan2
- B4GALT6 | c.481C>A p.L161I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.077); catalogued as COSV52702858; called by muse, mutect2, varscan2
- BAIAP2L2 | c.194G>A p.S65N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs1477122279; called by muse, mutect2, varscan2
- BATF | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54375717; called by muse, mutect2, varscan2
- BAZ1A | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV62409067, COSV62409929; called by muse, mutect2, varscan2
- BAZ1A | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs774051075, COSV100701080; called by muse, varscan2
- BAZ1A | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as rs778414647, COSV100701199; called by muse, varscan2
- BAZ1B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs1554575752, COSV59989118; called by muse, mutect2, varscan2
- BAZ2B | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 47/138 reads (34%) | catalogued as rs780189423, COSV58596651, COSV58605383; called by muse, mutect2, varscan2
- BBOF1 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780859463, COSV67454940; called by muse, mutect2, varscan2
- BBS2 | c.710G>A p.R237K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs377718970, COSV99802773; called by muse, mutect2, varscan2
- BBS4 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs121434632, CM011911; called by muse, mutect2, varscan2
- BCAS3 | c.1732G>T p.E578* (on ENST00000390652 / NM_001353144.2; = p.E563* on NM_017679.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV66775862; called by muse, varscan2
- BCHE | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.033); catalogued as rs779828972, COSV52253883; called by muse, mutect2, varscan2
- BCHE | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as rs749068794, COSV52256399; called by muse, mutect2, varscan2
- BCL6B | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99546442, COSV99546768; called by muse, mutect2, varscan2
- BCL7C | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs769214350; called by muse, mutect2, varscan2
- BCLAF1 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs78267720; called by muse, mutect2, varscan2
- BCLAF1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs62431287, COSV50356735; ClinVar: benign; called by mutect2, varscan2
- BCO2 | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV63062681; called by muse, mutect2, varscan2
- BCORL1 | c.2600C>T p.S867L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs1359885552, COSV54408558; called by muse, mutect2, varscan2
- BCR | c.3214C>T p.R1072C | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs780858887, COSV100005984; called by muse, mutect2, varscan2
- BDP1 | c.7064C>A p.S2355Y | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62435962; called by muse, varscan2
- BEND2 | c.1295T>C p.L432S | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV66217543; called by muse, varscan2
- BEND5 | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.079); catalogued as rs756106934; called by muse, varscan2
- BEND5 | c.784C>A p.L262I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100884075; called by muse, varscan2
- BFSP1 | c.1104G>T p.K368N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV64900478; called by muse, mutect2, varscan2
- BGN | c.351C>T p.Y117= | Splice Region (SNP) | VAF 51/118 reads (43%) | catalogued as rs782268995, COSV100525343; called by muse, mutect2, varscan2
- BICD2 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs780485203; called by muse, mutect2, varscan2
- BICDL2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1195939348; called by muse, varscan2
- BIRC3 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV99680230; called by muse, mutect2, varscan2
- BIRC6 | c.7072C>A p.L2358I | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); catalogued as COSV70198072; called by muse, mutect2, varscan2
- BIRC6 | c.9817G>A p.E3273K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70198988; called by muse, mutect2, varscan2
- BIRC6 | c.13602A>T p.K4534N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.51); catalogued as COSV70204315; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3943G>T p.D1315Y | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777538785; called by muse, mutect2, varscan2
- BLM | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.459); catalogued as CD073575, COSV61923172; called by muse, mutect2, varscan2
- BLNK | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV56410837; called by muse, varscan2
- BLZF1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV61393075; called by mutect2, varscan2
- BMX | c.732G>A p.W244* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as rs1474913393; called by muse, mutect2, varscan2
- BNC2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773045476, COSV66142375; called by muse, mutect2, varscan2
- BOD1L1 | c.8635C>T p.R2879C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756166010; called by muse, mutect2, varscan2
- BOD1L1 | c.5465C>T p.S1822L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs771167771, COSV99239039; called by muse, mutect2, varscan2
- BOD1L1 | c.1836T>G p.I612M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV50075731; called by muse, mutect2, varscan2
- BPI | c.573A>C p.K191N (on ENST00000262865; = p.K187N on NM_001725.3) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.194); catalogued as COSV99480370; called by muse, mutect2, varscan2
- BPIFA1 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.361); catalogued as COSV62824637; called by muse, mutect2, varscan2
- BPIFA2 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.389); catalogued as COSV53610755, COSV53612860; called by muse, mutect2, varscan2
- BRAF | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs397507472, COSV56068050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRAF | c.882C>A p.F294L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.248); catalogued as COSV56101984; called by muse, mutect2, varscan2
- BRCA2 | c.1334C>A p.S445Y | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs786202373, COSV66461942; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.2015G>T p.R672I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV66455946; called by muse, mutect2, varscan2
- BRD2 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs137898499; called by muse, mutect2
- BRF1 | c.1534C>T p.R512* | Nonsense Mutation (SNP) | VAF 9/25 reads (36%) | catalogued as rs1183617977, COSV100527830; called by muse, mutect2, varscan2
- BRINP1 | c.5A>C p.N2T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.037); catalogued as COSV56295266; called by muse, mutect2, varscan2
- BRIX1 | c.337A>C p.N113H | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59130769; called by muse, mutect2, varscan2
- BRMS1L | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV53762926; called by muse, mutect2
- BRPF3 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100326227; called by muse, mutect2, varscan2
- BRWD1 | c.6818C>A p.S2273Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV59000362, COSV59000786; called by muse, mutect2, varscan2
- BRWD3 | c.3052G>T p.E1018* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV64751271; called by muse, mutect2, varscan2
- BSCL2 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs749917957; ClinVar: uncertain significance; called by muse, varscan2
- BSG | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs1212040846; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780909487, COSV58283320; called by muse, varscan2
- BTBD7 | c.1229C>A p.S410Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58283843; called by muse, varscan2
- BTC | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs376806249; called by muse, mutect2, varscan2
- BTNL3 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs778473610, COSV61564442; called by muse, mutect2, varscan2
- BUB1B | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs766052877, COSV55010530; called by muse, varscan2
- BZW2 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV51753879; called by muse, mutect2, varscan2
- C10orf88 | c.266C>A p.S89Y | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV64404297; called by muse, mutect2, varscan2
- C10orf90 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs756132520, COSV52952082; called by muse, mutect2, varscan2
- C11orf1 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs782079457, COSV52791006; called by muse, mutect2, varscan2
- C11orf24 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs762505603, COSV100422540; called by muse, mutect2, varscan2
- C11orf58 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1198004760; called by muse, mutect2, varscan2
- C11orf68 | c.506G>A p.R169H (on ENST00000530188; = p.R210H on NM_031450.4) | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs1419650941; called by muse, mutect2, varscan2
- C12orf29 | c.277T>G p.F93V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); catalogued as rs1328758937; called by muse, mutect2, varscan2
- C12orf4 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs532268400, COSV54205508; called by muse, mutect2, varscan2
- C12orf50 | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs145797004; called by muse, varscan2
- C12orf71 | c.767G>T p.R256I | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV70282623; called by muse, mutect2, varscan2
- C17orf58 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as rs542001619, COSV57817054; called by muse, mutect2, varscan2
- C1GALT1C1L | c.708T>G p.D236E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs756180281; called by muse, mutect2, varscan2
- C1orf105 | c.190T>G p.L64V | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as COSV104383390; called by muse, mutect2, varscan2
- C1orf116 | c.1556C>T p.S519L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs754259052; called by muse, varscan2
- C1orf146 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753716244, COSV100950216; called by muse, mutect2, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as rs147997086, COSV64596556; called by muse, mutect2, varscan2
- C20orf194 | c.3393C>A p.F1131L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); catalogued as COSV52691108; called by muse, mutect2, varscan2
- C2CD2L | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs750402851, COSV60883825; called by muse, mutect2, varscan2
- C3 | c.2464G>A p.E822K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV55573420; called by muse, mutect2, varscan2
- C3orf52 | c.342G>T p.K114N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs1233017733; called by muse, mutect2, varscan2
- C4BPB | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759251062, COSV54691571; called by muse, mutect2, varscan2
- C5 | c.3676C>T p.R1226C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs537101618, COSV56327108; called by muse, mutect2, varscan2
- C5AR1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374799160; called by muse, mutect2, varscan2
- C5orf34 | c.778C>A p.H260N | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV60931865; called by muse, mutect2, varscan2
- C6 | c.2273C>A p.S758Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV54706420; called by muse, mutect2, varscan2
- C6 | c.1161G>T p.K387N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as COSV54712510; called by muse, mutect2, varscan2
- C8orf34 | c.428G>T p.R143I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1327430793, COSV61370989, COSV61395585; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- C8orf76 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369018257; called by muse, mutect2, varscan2
- C9 | c.43G>T p.E15* | Nonsense Mutation (SNP) | VAF 4/21 reads (19%) | catalogued as COSV54678835; called by mutect2, varscan2
- CAB39L | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs200343559, COSV61716390; called by muse, mutect2, varscan2
- CABP1 | c.706G>T p.E236* (on ENST00000316803 / NM_001033677.1; = p.E33* on NM_004276.5) | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV56459655; called by muse, mutect2, varscan2
- CABP1 | c.802G>A p.E268K (on ENST00000316803 / NM_001033677.1; = p.E65K on NM_004276.5) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1328676871, COSV56458203; called by muse, mutect2, varscan2
- CACHD1 | c.2312C>A p.S771Y | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99261328; called by muse, mutect2, varscan2
- CACHD1 | c.3418C>T p.R1140C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200240221, COSV51547290; called by muse, mutect2, varscan2
- CACNA1B | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771121255; called by muse, mutect2, varscan2
- CACNA1B | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1259261506, COSV53124713; called by muse, mutect2, varscan2
- CACNA1C | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV59701197; called by muse, mutect2, varscan2
- CACNA1C | c.2888C>A p.S963Y | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59707867, COSV59721607; called by muse, mutect2, varscan2
- CACNA1D | c.4720C>T p.R1574W (on ENST00000350061 / NM_001128840.3; = p.R1594W on NM_000720.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55442346; called by muse, mutect2, varscan2
- CACNA1E | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762966764, COSV62402445, COSV62404710; called by muse, mutect2, varscan2
- CACNA2D3 | c.3103-2A>C p.X1035_splice (on ENST00000288197; = p.Y1034S on NM_018398.3) | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV55516280, COSV55522197; called by muse, mutect2, varscan2
- CACNB3 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs752369498, COSV56397590; called by muse, mutect2, varscan2
- CACNB4 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs1304491659, COSV52390979; called by muse, mutect2, varscan2
- CACNG4 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs751878206, COSV50924945; called by muse, varscan2
- CACUL1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs746314775, COSV60993535; called by muse, mutect2, varscan2
- CADM2 | c.536G>A p.R179H (on ENST00000407528 / NM_001167674.2; = p.R181H on NM_153184.4) | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs1416693838, COSV67356966, COSV67406817; called by muse, mutect2, varscan2
- CADM3 | c.353G>A p.R118Q (on ENST00000368125 / NM_001127173.3; = p.R152Q on NM_021189.5) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.969); catalogued as rs372345467; called by muse, mutect2, varscan2
- CADPS2 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1457955627, COSV57358802; called by muse, mutect2, varscan2
- CALCOCO1 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs1267227310, COSV50416408; called by muse, mutect2, varscan2
- CALHM6 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100889440; called by muse, mutect2, varscan2
- CAMK4 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260987863, COSV56661321; called by muse, varscan2
- CAMK4 | c.549C>T p.I183= | Splice Region (SNP) | VAF 7/21 reads (33%) | catalogued as rs267600313, COSV56662562; called by muse, varscan2
- CAMKK2 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV61214188; called by muse, mutect2
- CAMSAP1 | c.4491G>T p.K1497N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56720602; called by muse, mutect2, varscan2
- CAP1 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV61223935; called by muse, mutect2, varscan2
- CAPN11 | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV67237124; called by mutect2, varscan2
- CAPN5 | c.1297G>A p.E433K (on ENST00000456580; = p.E393K on NM_004055.5) | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs369845664; called by muse, mutect2, varscan2
- CAPN9 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99681116; called by muse, mutect2, varscan2
- CAPRIN2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51833997; called by muse, mutect2, varscan2
- CAPS2 | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.702); catalogued as COSV100157795; called by muse, mutect2, varscan2
- CARD6 | c.1522A>C p.T508P | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs367957715; called by muse, mutect2, varscan2
- CARM1 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs752773089; called by muse, mutect2, varscan2
- CARMIL2 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748613858; called by muse, varscan2
- CARNMT1 | c.571A>C p.N191H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV104429005; called by muse, mutect2, varscan2
- CASD1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51973239; called by muse, mutect2, varscan2
- CASP5 | c.436C>A p.L146I | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0.269); catalogued as COSV52827799; called by muse, mutect2
- CASP8AP2 | c.3182C>A p.S1061* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | catalogued as rs1471516809, COSV99387681; called by muse, mutect2
- CATSPER1 | c.2027C>T p.T676M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs376917892; called by muse, mutect2, varscan2
- CATSPERE | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.203); catalogued as rs746462117; called by muse, mutect2, varscan2
- CATSPERG | c.3352G>A p.A1118T | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs555054175, COSV99286802; called by muse, mutect2, varscan2
- CBFA2T2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs146788442; called by muse, mutect2, varscan2
- CBL | c.2489G>T p.R830I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs750959492, COSV50666270; called by mutect2, varscan2
- CBLB | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51424023; called by muse, mutect2, varscan2
- CBLL1 | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.061); catalogued as rs756843724, COSV56027915, COSV56028047; called by muse, mutect2, varscan2
- CBX8 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as rs1457754607; called by muse, mutect2, varscan2
- CBY2 | c.63G>A p.W21* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as COSV60117487, COSV60119089; called by muse, mutect2, varscan2
- CC2D2A | c.3584T>G p.F1195C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as CD096682; called by muse, mutect2, varscan2
- CCAR1 | c.2102A>C p.K701T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.307); catalogued as rs369000905; called by muse, varscan2
- CCDC116 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141137219; called by muse, mutect2, varscan2
- CCDC122 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | catalogued as COSV55708664, COSV99865881; called by muse, mutect2, varscan2
- CCDC125 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV67288917; called by muse, varscan2
- CCDC125 | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as rs771037105, COSV101143677; called by muse, mutect2, varscan2
- CCDC136 | c.2021G>A p.R674Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs375639275; called by mutect2, varscan2
- CCDC141 | c.3301C>A p.L1101I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.664); catalogued as COSV55371878, COSV55381669; called by muse, mutect2, varscan2
- CCDC144A | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as rs755502003, COSV60698807, COSV60700532; called by muse, mutect2, varscan2
- CCDC144A | c.3465C>A p.F1155L | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1344224233; called by muse, mutect2, varscan2
- CCDC144A | c.3610G>T p.E1204* | Nonsense Mutation (SNP) | VAF 38/150 reads (25%) | catalogued as COSV60700880, COSV60701178; called by muse, varscan2
- CCDC144A | c.3646G>A p.E1216K | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.267); catalogued as rs750175196, COSV60701277; called by muse, varscan2
- CCDC15 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as rs201773360; called by muse, varscan2
- CCDC15 | c.1585G>A p.G529S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV61083506; called by muse, mutect2, varscan2
- CCDC158 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as rs1231792251, COSV66355381, COSV66355441; called by muse, mutect2, varscan2
- CCDC159 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.889); catalogued as rs200265497; called by muse, mutect2, varscan2
- CCDC160 | c.14G>T p.R5I | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs947108162, COSV100892084; called by muse, mutect2, varscan2
- CCDC171 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371347398, COSV52640634; called by muse, mutect2, varscan2
- CCDC173 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs748548666, COSV69572502; called by muse, mutect2, varscan2
- CCDC180 | c.4775C>T p.S1592L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs566316997, COSV63826671; called by muse, mutect2, varscan2
- CCDC186 | c.1706C>A p.S569Y | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV104427815; called by muse, varscan2
- CCDC25 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1451166482, COSV100738332; called by muse, mutect2, varscan2
- CCDC27 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767384697, COSV53903557; called by muse, mutect2, varscan2
- CCDC51 | c.327C>A p.F109L | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56493782; called by muse, mutect2, varscan2
- CCDC54 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs756856656, COSV53758368; called by muse, mutect2, varscan2
- CCDC59 | c.570C>A p.F190L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV56281065; called by muse, mutect2, varscan2
- CCDC69 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748092478; called by muse, mutect2
- CCDC73 | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs377693069, COSV104406438; called by muse, mutect2, varscan2
- CCDC73 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV58795993; called by muse, mutect2
- CCDC73 | c.982G>T p.E328* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as rs1302619987, COSV100067976, COSV58796349; called by muse, mutect2, varscan2
- CCDC74A | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs752719318, COSV54608496; called by muse, mutect2, varscan2
- CCDC85A | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.381); catalogued as rs187792610, COSV68150980; called by muse, mutect2, varscan2
- CCDC87 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs750291738, COSV59578583; called by mutect2, varscan2
- CCDC88A | c.4148T>G p.F1383C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99710624; called by muse, mutect2
- CCDC96 | c.755A>C p.K252T | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs768301828; called by muse, varscan2
- CCL25 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs541796418, COSV53664632; called by muse, mutect2, varscan2
- CCM2 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs372613654; called by muse, mutect2, varscan2
- CCN1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.148); catalogued as rs1319797757, COSV71704261; called by muse, mutect2, varscan2
- CCN4 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV51533675; called by muse, mutect2, varscan2
- CCN6 | c.1016G>T p.R339I | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.768); catalogued as COSV57889108; called by muse, mutect2, varscan2
- CCNB3 | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV52078569; called by muse, mutect2, varscan2
- CCNJL | c.1247C>T p.T416I | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as rs1351639516, COSV57446282; called by muse, mutect2, varscan2
- CCNT2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV51472643; called by muse, mutect2, varscan2
- CCR2 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 22/58 reads (38%) | catalogued as COSV99432782; called by muse, mutect2, varscan2
- CCT3 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745774938, COSV55290266; called by mutect2, varscan2
- CCT8 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 15/67 reads (22%) | catalogued as COSV54506982; called by muse, mutect2, varscan2
- CCT8L2 | c.1643A>G p.E548G | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1568981375; called by muse, mutect2, varscan2
- CD101 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as rs1362169599, COSV56716851; called by muse, mutect2, varscan2
- CD109 | c.859A>C p.N287H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV99754595; called by muse, mutect2, varscan2
- CD1B | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.262); catalogued as rs372119438; called by muse, mutect2
- CD1E | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs1469396381, COSV63771045; called by muse, mutect2, varscan2
- CD22 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.044); catalogued as rs143516468; called by muse, mutect2, varscan2
- CD244 | c.1069C>T p.R357* (on ENST00000368033 / NM_001166663.2; = p.R352* on NM_016382.4) | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as rs138354575; called by muse, mutect2, varscan2
- CD27 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.888); catalogued as rs1297439808, COSV56946768; called by muse, mutect2, varscan2
- CD2AP | c.1306A>C p.K436Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63759172; called by muse, mutect2, varscan2
- CD300E | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.317); catalogued as COSV60790459; called by muse, mutect2, varscan2
- CD300LB | c.68C>A p.S23Y | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.492); catalogued as COSV58726314; called by muse, mutect2, varscan2
- CD36 | c.500C>A p.S167Y | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV99987982; called by muse, mutect2, varscan2
- CD36 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs4645507; called by muse, mutect2, varscan2
- CD3G | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs1344032715; called by muse, mutect2, varscan2
- CD40LG | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.257); catalogued as rs1252281345, CM016294, COSV65699146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD82 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs746166676; called by muse, mutect2
- CD86 | c.917G>T p.R306I (on ENST00000330540 / NM_175862.5; = p.R300I on NM_006889.4) | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV52606109; called by muse, varscan2
- CD96 | c.513T>G p.I171M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV51916370; called by muse, mutect2, varscan2
- CD99 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.948); catalogued as rs774386901; called by muse, mutect2, varscan2
- CDAN1 | c.534C>A p.F178L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51176033; called by muse, mutect2, varscan2
- CDC27 | c.269A>C p.Q90P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.491); catalogued as COSV50385781; called by muse, varscan2
- CDC37L1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as COSV101116654; called by muse, mutect2, varscan2
- CDC5L | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749621430, COSV101015221; called by muse, mutect2, varscan2
- CDC5L | c.1717G>T p.E573* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV101014798; called by muse, mutect2, varscan2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, mutect2, varscan2
- CDH1 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs121964873, COSV55736787, COSV55737055; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH10 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52574144; called by muse, varscan2
- CDH10 | c.826C>A p.L276I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV52597858; called by muse, mutect2, varscan2
- CDH10 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100049911; called by muse, mutect2, varscan2
- CDH12 | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 15/33 reads (45%) | catalogued as COSV66425492; called by muse, mutect2, varscan2
- CDH12 | c.1861C>A p.L621I | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs1337574484, COSV66387568; called by muse, mutect2, varscan2
- CDH12 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66389351; called by muse, mutect2, varscan2
- CDH23 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as rs374527066; called by muse, mutect2, varscan2
- CDH23 | c.3370C>A p.L1124M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs865780707; called by muse, mutect2
- CDH23 | c.9616C>T p.R3206C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs778711089; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH7 | c.1933G>T p.D645Y | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100541324; called by muse, mutect2, varscan2
- CDH7 | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as COSV100542013; called by muse, mutect2, varscan2
- CDH8 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.722); catalogued as COSV100184892; called by muse, varscan2
- CDHR2 | c.2793G>T p.E931D | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs543624964; called by muse, mutect2, varscan2
- CDK16 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs1390334897; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as rs774457063; called by muse, varscan2
- CDKL5 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1466254546, COSV66111058; called by muse, mutect2, varscan2
- CDKN3 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as COSV53593813; called by muse, mutect2, varscan2
- CDNF | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as rs1168824330, COSV65805700, COSV65805971, COSV65806275; called by muse, mutect2, varscan2
- CDO1 | c.223C>A p.L75I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV51666153; called by muse, mutect2, varscan2
- CDON | c.1778C>T p.T593M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.28); PolyPhen benign (0.117); catalogued as rs1410096982; called by muse, mutect2, varscan2
- CDS1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs776915359, COSV55690760; called by muse, mutect2, varscan2
- CEACAM6 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.23); catalogued as COSV52268847; called by muse, mutect2, varscan2
- CECR2 | c.2671C>T p.R891W (on ENST00000342247 / NM_001290047.2; = p.R708W on NM_001290046.1) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763950393, COSV52838555; called by muse, mutect2, varscan2
- CELA1 | c.758A>T p.N253I | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV99529904; called by muse, mutect2, varscan2
- CELA2A | c.132C>A p.V44= | Splice Region (SNP) | VAF 34/90 reads (38%) | catalogued as COSV62747224; called by muse, mutect2, varscan2
- CEMIP | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778020593, COSV54992323; called by muse, mutect2, varscan2
- CEMIP | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs181470477, COSV99585950; called by muse, mutect2, varscan2
- CEMIP | c.3190G>A p.E1064K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); catalogued as rs756288191, COSV54993786; called by muse, mutect2, varscan2
- CEMIP2 | c.834A>C p.K278N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV65485961; called by muse, varscan2
- CENPC | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56622895; called by muse, mutect2, varscan2
- CENPE | c.7126A>G p.T2376A | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as rs777495974; called by muse, mutect2, varscan2
- CENPE | c.6082C>A p.H2028N | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.081); catalogued as rs1478350784; called by muse, mutect2, varscan2
- CENPF | c.3598G>T p.E1200* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV100871552, COSV65276017; called by muse, mutect2, varscan2
- CENPF | c.5896G>T p.E1966* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV65273880; called by muse, mutect2, varscan2
- CENPI | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99515576; called by muse, mutect2, varscan2
- CENPL | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs767450186; called by muse, mutect2, varscan2
- CENPO | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs150968453; called by muse, mutect2, varscan2
- CEP152 | c.2129G>T p.R710I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as rs1022617230, COSV57857950; called by muse, mutect2, varscan2
- CEP170B | c.1247G>A p.R416Q (on ENST00000453495; = p.R345Q on NM_015005.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs773293486, COSV69023827; called by muse, mutect2, varscan2
- CEP192 | c.7081G>A p.D2361N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV58063571; called by muse, varscan2
- CEP250 | c.3133C>T p.R1045* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as rs775811770; called by muse, mutect2, varscan2
- CEP290 | c.5777G>A p.R1926Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs778030031, CM111853, COSV58351378; called by muse, mutect2, varscan2
- CEP290 | c.4990G>T p.E1664* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100467681; called by muse, varscan2
- CEP290 | c.4864C>T p.R1622C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs746576984, COSV58352317; called by muse, mutect2, varscan2
- CEP290 | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.096); catalogued as rs764117043; called by muse, mutect2, varscan2
- CEP290 | c.1782G>T p.L594F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1283118657; called by muse, mutect2, varscan2
- CEP290 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 22/60 reads (37%) | catalogued as COSV99898801; called by muse, mutect2, varscan2
- CEP350 | c.1108C>T p.R370* | Nonsense Mutation (SNP) | VAF 32/70 reads (46%) | catalogued as COSV62609464; called by muse, mutect2, varscan2
- CEP57 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs774404375, COSV57687405; called by muse, varscan2
- CEP76 | c.88G>T p.E30* | Nonsense Mutation (SNP) | VAF 27/69 reads (39%) | catalogued as rs1399814388, COSV50865503; called by muse, mutect2, varscan2
- CEP78 | c.1602C>A p.F534L (on ENST00000424347 / NM_001349840.2; = p.F535L on NM_032171.3) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99450207; called by muse, mutect2, varscan2
- CEP95 | c.1816C>T p.R606* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs782817185, COSV73609180; called by muse, mutect2, varscan2
- CERKL | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as rs1430224051, COSV59205143; called by muse, mutect2, varscan2
- CERS3 | c.1081G>T p.E361* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as rs1423384225, COSV52568677; called by muse, mutect2, varscan2
- CERS4 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as rs995547822, COSV52170304; called by muse, mutect2, varscan2
- CES3 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.013); catalogued as rs375973123; called by muse, mutect2, varscan2
- CES5A | c.1713C>A p.F571L (on ENST00000290567 / NM_001143685.2; = p.F521L on NM_145024.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99308283; called by muse, varscan2
- CETN1 | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV59121116; called by muse, mutect2, varscan2
- CETN3 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51618407; called by muse, mutect2, varscan2
- CFAP206 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.346); catalogued as rs147497097, COSV51534705, COSV99739391; called by muse, mutect2, varscan2
- CFAP298 | c.872G>T p.*291Lext*17 | Nonstop Mutation (SNP) | VAF 21/60 reads (35%) | catalogued as COSV51593728; called by muse, mutect2, varscan2
- CFAP36 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as rs763494988, COSV59117634; called by muse, mutect2, varscan2
- CFAP36 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV55408073, COSV99702693; called by muse, mutect2, varscan2
- CFAP410 | c.367A>G p.N123D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs780892823; called by muse, mutect2, varscan2
- CFAP44 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs759451649, COSV55610814; called by muse, mutect2, varscan2
- CFAP45 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV63648087; called by muse, mutect2, varscan2
- CFAP45 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs200252683, COSV63647949; called by muse, mutect2, varscan2
- CFAP47 | c.1721G>A p.R574H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1488278882; called by muse, mutect2, varscan2
- CFAP53 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.066); catalogued as rs754896236; called by muse, mutect2, varscan2
- CFAP53 | c.1305G>T p.E435D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV68351567, COSV68351916; called by muse, varscan2
- CFAP53 | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs199505634; called by muse, varscan2
- CFAP54 | c.6477C>T p.I2159= | Splice Region (SNP) | VAF 16/61 reads (26%) | catalogued as rs12322639, COSV100733202; called by muse, mutect2, varscan2
- CFAP54 | c.6545G>T p.R2182I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV61574975; called by muse, mutect2, varscan2
- CFAP57 | c.1580T>G p.L527R | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV65264974; called by muse, mutect2, varscan2
- CFAP58 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV104397677, COSV57211378, COSV57213574; called by muse, mutect2, varscan2
- CFAP61 | c.2068A>G p.M690V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs762103927; called by muse, mutect2, varscan2
- CFAP70 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs766866421, COSV60285375; called by muse, mutect2, varscan2
- CFAP70 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100161147; called by mutect2, varscan2
- CFAP91 | c.2220G>T p.K740N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.021); catalogued as COSV99847307; called by muse, mutect2, varscan2
- CFAP97 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as rs377195111; called by muse, varscan2
- CGN | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754175873, COSV54971583; called by muse, mutect2, varscan2
- CHAF1B | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.53); catalogued as COSV58440118, COSV58441757; called by muse, mutect2, varscan2
- CHD1 | c.2699G>A p.R900Q | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52337905; called by muse, mutect2, varscan2
- CHD5 | c.3043G>A p.D1015N | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as rs1222325613, COSV52409657; called by muse, mutect2, varscan2
- CHD8 | c.2004C>A p.F668L (on ENST00000646647 / NM_001170629.2; = p.F389L on NM_020920.4) | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1445246220, COSV67869656; called by muse, mutect2, varscan2
- CHD9 | c.2776G>T p.E926* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV54608262; called by muse, mutect2, varscan2
- CHD9 | c.4138G>A p.D1380N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1395308687, COSV54613241; called by muse, mutect2, varscan2
- CHD9 | c.5758C>T p.R1920C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs960956466, COSV54609782; called by muse, mutect2, varscan2
- CHD9 | c.6395C>T p.S2132F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV54609002; called by muse, mutect2, varscan2
- CHGB | c.363G>T p.E121D | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV66759568, COSV66760586; called by muse, mutect2, varscan2
- CHGB | c.1680G>T p.K560N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV66759675; called by muse, mutect2, varscan2
- CHL1 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV56586240; called by muse, mutect2, varscan2
- CHL1 | c.536G>T p.R179I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162204356, COSV99850158; called by muse, mutect2, varscan2
- CHL1 | c.3352G>T p.D1118Y (on ENST00000397491 / NM_001253387.1; = p.D1134Y on NM_006614.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56602829; called by muse, mutect2, varscan2
- CHRM3 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV99697378; called by muse, mutect2, varscan2
- CHRNA2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as rs774054592, COSV53557297; called by muse, mutect2, varscan2
- CHRNB2 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145893879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.837); catalogued as COSV100346110; called by muse, mutect2, varscan2
- CHST15 | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs878912191, COSV100655059; called by muse, mutect2, varscan2
- CHST6 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386618106, CM034022, COSV60001140; called by muse, mutect2
- CHSY1 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as rs773884567, COSV54252346; called by muse, mutect2, varscan2
- CHSY3 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs149892119; called by muse, mutect2, varscan2
- CIITA | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs745939838, COSV60856466; called by muse, mutect2, varscan2
- CILP2 | c.3226G>A p.A1076T | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs1180523127; called by muse, mutect2
- CIP2A | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs779731478, COSV55419478; called by muse, mutect2, varscan2
- CKAP2L | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs535556276, COSV56698151; called by muse, varscan2
- CKAP2L | c.1469G>T p.R490I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1431111093; called by muse, varscan2
- CLASP1 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99757340; called by muse, mutect2, varscan2
- CLCA1 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.242); catalogued as COSV52328639, COSV99322747; called by muse, mutect2, varscan2
- CLCA1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs753995315, COSV52324938, COSV52328286; called by muse, mutect2, varscan2
- CLCA1 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as rs139300046; called by muse, mutect2, varscan2
- CLCA2 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV100991640; called by muse, mutect2, varscan2
- CLCA2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.396); catalogued as COSV100991319; called by muse, mutect2, varscan2
- CLCA2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs750282125; called by muse, mutect2, varscan2
- CLCC1 | c.523G>A p.E175K (on ENST00000356970 / NM_001377464.1; = p.E125K on NM_015127.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as rs1215323809, COSV56762690; called by muse, mutect2, varscan2
- CLCN1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs189963844, CM993827; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCN7 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765444328, CM099579, COSV51968811; called by muse, mutect2, varscan2
- CLDN1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV55043691; called by muse, mutect2, varscan2
- CLDN12 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as rs767199576, COSV55306830; called by muse, mutect2
- CLDN4 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV99936310; called by muse, mutect2, varscan2
- CLDN8 | c.529G>A p.V177I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99729979; called by muse, mutect2, varscan2
- CLEC4F | c.824G>T p.R275I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV55478546; called by muse, mutect2, varscan2
9,992 further variants in this file (7,774 protein-altering or splice-affecting, 1,938 silent, 280 other) are not listed here.
